Somatic mutation profile of tumor specimen TCGA-44-6147-01B (aliquot TCGA-44-6147-01B-06D-A271-08) from TCGA case TCGA-44-6147, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 67.4 years (24,631 days).
Specimen TCGA-44-6147-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4899380-8783-4cdb-93fb-862e8f9ff402.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-6147-10A (Blood Derived Normal), aliquot TCGA-44-6147-10A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fde996d6-190e-4084-9b51-ab8b9e9ceea6

The open-access MAF lists 157 somatic variants for this specimen: 106 protein-altering or splice-affecting, 50 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 94, Silent 50, Nonsense Mutation 4, Frame Shift Del 4, Frame Shift Ins 1, Intron 1, In Frame Del 1, Splice Site 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2303G>T p.S768I | Missense Mutation (SNP) | VAF 32/123 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913465, COSV51768106, COSV51821681, COSV51833841; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- TP53 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 17/80 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as rs11540654, CM115383, CM134053, CM984590, COSV52662399, COSV52668419, COSV52680444, COSV53132492; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSM2B | c.1671A>C p.K557N | Missense Mutation (SNP) | VAF 68/338 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61660186; called by muse, mutect2, varscan2
- ADGRB3 | c.3152A>G p.D1051G | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99484022; called by muse, mutect2, varscan2
- ADGRF2 | c.616T>A p.W206R (on ENST00000296862 / NM_001368115.2; = p.W138R on NM_153839.7) | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV57292367; called by muse, mutect2, varscan2
- ALMS1 | c.2445G>T p.E815D | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.106); catalogued as COSV100041528; called by muse, mutect2, varscan2
- ATRX | c.5257A>G p.N1753D | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64884374; called by muse, mutect2, varscan2
- CACNA1E | c.5494G>T p.D1832Y | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62429521; called by muse, mutect2
- CARD14 | c.2159G>A p.R720H | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs202094920, COSV60126797; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCDC73 | c.1835A>G p.E612G | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.04); catalogued as COSV58805356; called by mutect2, varscan2
- CD101 | c.1473G>T p.W491C | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.961); catalogued as COSV99869248; called by muse, mutect2, varscan2
- CD101 | c.1474G>T p.A492S | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.715); catalogued as COSV99869256; called by muse, mutect2, varscan2
- CD93 | c.98G>C p.G33A | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.089); catalogued as COSV55669140; called by muse, mutect2, varscan2
- CDH6 | c.709C>A p.Q237K | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.829); catalogued as COSV54068746; called by muse, mutect2, varscan2
- COL23A1 | c.436T>C p.Y146H | Missense Mutation (SNP) | VAF 23/232 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV66799365; called by muse, mutect2, varscan2
- CPA4 | c.277G>T p.D93Y | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55985261; called by muse, mutect2, varscan2
- CPT1A | c.1798G>T p.G600W | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55761679; called by mutect2, varscan2
- CSMD3 | c.7846G>T p.G2616W (on ENST00000297405 / NM_001363185.1; = p.G2512W on NM_052900.3) | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52331340; called by muse, mutect2, varscan2
- CTNNA1 | c.128A>T p.N43I | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.562); catalogued as COSV57081955; called by muse, mutect2, varscan2
- CTTNBP2 | c.2961T>G p.D987E | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV50484331; called by muse, mutect2, varscan2
- DCLK1 | c.1774G>T p.D592Y | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV55213373; called by muse, mutect2, varscan2
- DCLK3 | c.401G>T p.G134V | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.942); catalogued as COSV69364876; called by muse, mutect2, varscan2
- DHX37 | c.1135G>A p.V379M | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.22); catalogued as rs779437822, COSV58131658; called by mutect2, varscan2
- DNAH7 | c.5337G>T p.K1779N | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as COSV100415105; called by muse, mutect2, varscan2
- EGFR | c.2305G>T p.V769L | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.572); catalogued as rs147149347, COSV51802272, COSV51811749; ClinVar: uncertain significance; called by muse, mutect2
- EPDR1 | c.470C>G p.A157G | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.259); catalogued as COSV52258762, COSV52262160; called by muse, mutect2, varscan2
- EXOC4 | c.2117A>T p.D706V | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.106); catalogued as COSV54124828; called by muse, mutect2, varscan2
- FAM135A | c.587C>T p.P196L (on ENST00000370479 / NM_001351599.1; = p.P153L on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV99525375; called by muse, mutect2
- FAM83B | c.1485G>T p.W495C | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.817); catalogued as COSV60927347; called by muse, mutect2, varscan2
- FLG | c.7423G>T p.G2475* | Nonsense Mutation (SNP) | VAF 159/534 reads (30%) | catalogued as COSV64250568; called by muse, mutect2, varscan2
- FOXL1 | c.1029C>A p.H343Q | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV100206133; called by muse, mutect2, varscan2
- FSCB | c.2296G>T p.A766S | Missense Mutation (SNP) | VAF 45/210 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.494); catalogued as rs1246242313, COSV100468972; called by muse, mutect2, varscan2
- GABRA6 | c.523G>C p.G175R | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50896119; called by muse, mutect2, varscan2
- GRM1 | c.1329G>T p.K443N | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.434); catalogued as COSV99264716; called by muse, mutect2
- GZMA | c.592G>T p.A198S | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57057915; called by muse, mutect2, varscan2
- H6PD | c.1124A>T p.N375I | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV66232499; called by muse, mutect2, varscan2
- HMCN1 | c.13693delinsTT p.G4565Lfs*17 | Frame Shift Ins (INS) | VAF 6/65 reads (9%) | catalogued as COSV99623534; called by mutect2*, pindel
- IGKV3-11 | c.304G>T p.D102Y | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758486991; called by muse, mutect2, varscan2
- ITGA8 | c.1151G>T p.G384V | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV65229184; called by muse, mutect2
- ITGA8 | c.1150G>T p.G384W | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65225821; called by muse, mutect2
- ITIH6 | c.2668C>A p.P890T | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.093); catalogued as COSV54495150; called by muse, mutect2, varscan2
- KCNH7 | c.266C>A p.S89* | Nonsense Mutation (SNP) | VAF 6/61 reads (10%) | catalogued as COSV100036938, COSV59815024; called by muse, mutect2
- KCNJ6 | c.223C>A p.R75S | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55713174, COSV55724009; called by muse, mutect2, varscan2
- KCTD19 | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as COSV58575473; called by muse, mutect2, varscan2
- KRTAP10-3 | c.112G>T p.A38S | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV100552310, COSV59959098; called by muse, mutect2, varscan2
- LAMB4 | c.3890C>A p.S1297Y | Missense Mutation (SNP) | VAF 35/221 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as COSV52732020; called by muse, mutect2, varscan2
- MGAM | c.1230G>T p.Q410H | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72075973; called by muse, mutect2, varscan2
- MIOS | c.1887A>T p.L629F | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV60770827; called by muse, mutect2, varscan2
- MSH4 | c.1723A>G p.I575V | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as COSV54213468; called by muse, mutect2
- MTMR14 | c.1007G>T p.R336L | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM065043, COSV56004553, COSV56007889; called by muse, mutect2, varscan2
- MUC17 | c.11840C>A p.T3947N | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as rs1454428134, COSV60305354; called by muse, mutect2, varscan2
- NELL2 | c.1339G>T p.G447W | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61586363; called by muse, mutect2
- OPRL1 | c.654C>A p.C218* | Nonsense Mutation (SNP) | VAF 22/88 reads (25%) | catalogued as rs767233709, COSV61093080; called by muse, varscan2
- OR2M4 | c.605G>A p.C202Y | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV60709843; called by muse, mutect2, varscan2
- OR5T2 | c.236T>G p.M79R | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV57591116; called by muse, mutect2
- OR6C2 | c.595C>T p.L199F | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.015); catalogued as rs141026850; called by muse, mutect2
- PAK5 | c.2071G>T p.A691S | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV62030955; called by muse, mutect2
- PARM1 | c.340G>A p.G114S | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT tolerated (0.94); PolyPhen benign (0.012); catalogued as rs34305542; called by muse, varscan2
- PCDH11X | c.338C>A p.A113D | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV53508284; called by muse, mutect2, varscan2
- PCDHA5 | c.2226C>A p.S742R | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.202); catalogued as rs1210626259, COSV100972164; called by muse, mutect2, varscan2
- PDE1B | c.1008G>T p.M336I | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54496708; called by muse, mutect2
- PEX1 | c.473-2A>T p.X158_splice | Splice Site (SNP) | VAF 5/53 reads (9%) | catalogued as COSV50421750; called by muse, mutect2
- PHF20 | c.2232G>C p.Q744H | Missense Mutation (SNP) | VAF 57/154 reads (37%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.993); catalogued as COSV64978119; called by muse, mutect2, varscan2
- PLEC | c.2132G>A p.R711Q (on ENST00000322810 / NM_201380.4; = p.R601Q on NM_000445.5) | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.516); catalogued as rs782426860, COSV100509142; ClinVar: uncertain significance; called by muse, mutect2
- PLPPR4 | c.1024G>T p.D342Y | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV64567841; called by muse, mutect2, varscan2
- PPARGC1B | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as rs1423459889; called by muse, mutect2
- PPM1D | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.246); catalogued as COSV59958225; called by muse, mutect2, varscan2
- PRRC2C | c.4617A>T p.E1539D (on ENST00000367742; = p.E1537D on NM_015172.4) | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV58914159; called by muse, mutect2, varscan2
- PTPRN2 | c.1216C>T p.H406Y | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67061108; called by muse, mutect2, varscan2
- PTPRZ1 | c.4699G>T p.D1567Y | Missense Mutation (SNP) | VAF 13/208 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV101100242; called by muse, mutect2
- RAB3C | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs764132162, COSV51442889; called by muse, mutect2, varscan2
- ROBO2 | c.2479G>A p.E827K | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs571504400, COSV59942096; called by muse, mutect2, varscan2
- SETX | c.142C>A p.H48N | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56395572; called by muse, mutect2, varscan2
- SKIV2L | c.2650G>T p.D884Y | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as COSV61715220; called by muse, mutect2, varscan2
- SORCS3 | c.1397C>A p.T466K | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.949); catalogued as COSV63826429; called by muse, mutect2, varscan2
- SYTL4 | c.519G>C p.Q173H | Missense Mutation (SNP) | VAF 7/152 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0.332); catalogued as COSV52172260; called by muse, mutect2
- TBC1D9B | c.2146G>A p.G716S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100783454; called by muse, varscan2
- TLR4 | c.582C>G p.D194E (on ENST00000355622 / NM_138554.5; = p.D154E on NM_003266.4) | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV62924355; called by muse, mutect2
- TMEM135 | c.637C>T p.H213Y | Missense Mutation (SNP) | VAF 13/159 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV59707117; called by muse, mutect2
- TRIM22 | c.955G>T p.D319Y | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV66090672, COSV66091936; called by muse, mutect2, varscan2
- TSGA10 | c.1668G>C p.Q556H | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61825934; called by muse, mutect2
- TSGA10 | c.1666C>T p.Q556* | Nonsense Mutation (SNP) | VAF 5/50 reads (10%) | catalogued as COSV61825938; called by muse, mutect2
- TSNARE1 | c.202G>T p.A68S | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.175); catalogued as COSV56184735; called by muse, mutect2, varscan2
- TULP1 | c.1546C>A p.L516I | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV57694001; called by muse, mutect2, varscan2
- UROC1 | c.1811G>C p.G604A | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760134412, COSV52039916; called by muse, mutect2
- VWA3B | c.868A>C p.S290R | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV68247114; called by muse, mutect2, varscan2
- ZBED9 | c.2452A>T p.S818C | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV71729802; called by muse, mutect2, varscan2
- ZDBF2 | c.1726T>A p.S576T | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV65630528; called by muse, mutect2
- ZNF226 | c.1127C>T p.S376F | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); catalogued as COSV56197085; called by muse, mutect2, varscan2
- ZNF474 | c.202C>A p.L68I | Missense Mutation (SNP) | VAF 33/217 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.06); catalogued as COSV56947867; called by muse, mutect2, varscan2
- DMWD | c.1088G>C p.R363P | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNA2 | c.1958_1976del p.G653Vfs*4 | Frame Shift Del (DEL) | VAF 29/201 reads (14%) | called by mutect2, pindel, varscan2
- GADD45A | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GGNBP2 | c.1450G>T p.D484Y | Missense Mutation (SNP) | VAF 34/196 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- KCNK18 | c.948C>A p.F316L | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCNT1 | c.1132C>A p.P378T (on ENST00000488444; = p.P397T on NM_020822.3) | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- MUC6 | c.2131del p.Q711Kfs*41 | Frame Shift Del (DEL) | VAF 12/90 reads (13%) | called by mutect2, varscan2
- MUC6 | c.2130C>A p.N710K | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by mutect2, varscan2
- OR3A2 | c.56C>A p.A19D | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.093); called by mutect2, varscan2
- R3HDM1 | c.3037G>A p.A1013T | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- RSF1 | c.2039T>G p.M680R | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.006); called by muse, mutect2
- TRBV3-1 | c.336C>G p.S112R | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRRAP | c.872del p.L291* | Frame Shift Del (DEL) | VAF 22/144 reads (15%) | called by mutect2, pindel, varscan2
- TTC7A | c.2521_2532del p.E841_A844del | In Frame Del (DEL) | VAF 6/31 reads (19%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.8602_8633del p.S2868Gfs*7 | Frame Shift Del (DEL) | VAF 26/194 reads (13%) | called by mutect2, pindel
- ZNF284 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.034); called by muse, mutect2
- ABCA6 | c.1302C>T p.F434= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV52645630; called by muse, mutect2
- ABHD5 | c.396G>A p.V132= | Silent (SNP) | VAF 52/253 reads (21%) | catalogued as rs373148191, COSV50007116; called by muse, mutect2, varscan2
- ALG10 | c.1125A>T p.P375= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV56794348; called by muse, mutect2, varscan2
- ANK2 | c.8832C>A p.T2944= | Silent (SNP) | VAF 39/231 reads (17%) | catalogued as COSV52191080; called by muse, mutect2, varscan2
- ANXA6 | c.879C>T p.F293= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as rs781611897, COSV100636816; called by muse, mutect2, varscan2
- ATP2B4 | c.96C>A p.L32= | Silent (SNP) | VAF 86/276 reads (31%) | catalogued as COSV58175372, COSV58184476; called by muse, mutect2, varscan2
- ATRNL1 | c.759C>T p.C253= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as rs200296037, COSV61814876; called by muse, mutect2, varscan2
- BPGM | c.723C>T p.I241= | Silent (SNP) | VAF 13/170 reads (8%) | called by muse, mutect2
- CACNA1S | c.1920C>T p.Y640= | Silent (SNP) | VAF 40/358 reads (11%) | catalogued as COSV62944214; called by muse, mutect2, varscan2
- CDIPT | c.54G>A p.R18= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV99570137; called by muse, mutect2
- CEP89 | c.2301C>T p.D767= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as rs201311820, COSV59868070; called by muse, varscan2
- CFAP46 | c.6015A>T p.T2005= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as COSV54160162; called by muse, varscan2
- CHRDL2 | c.76C>A p.R26= | Silent (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2
- CNTN5 | c.2598G>A p.V866= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV54361132; called by muse, mutect2, varscan2
- COL19A1 | c.3279T>C p.S1093= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV59589824; called by mutect2, varscan2
- COL22A1 | c.4308G>A p.E1436= | Silent (SNP) | VAF 40/118 reads (34%) | catalogued as COSV57347163, COSV57362679; called by muse, mutect2, varscan2
- COL24A1 | c.1518A>G p.P506= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV65314980; called by muse, mutect2, varscan2
- CSMD2 | c.1825C>T p.L609= | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as rs769998248, COSV53957048; called by muse, mutect2, varscan2
- CTSG | c.99C>A p.P33= | Silent (SNP) | VAF 53/186 reads (28%) | catalogued as COSV53537038; called by muse, mutect2, varscan2
- DCHS1 | c.1728C>A p.P576= | Silent (SNP) | VAF 7/79 reads (9%) | catalogued as COSV100201653; called by muse, mutect2
- DHODH | c.393C>T p.P131= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as COSV99536801; called by muse, mutect2
- DISP2 | c.2352C>A p.G784= | Silent (SNP) | VAF 17/106 reads (16%) | catalogued as COSV51145547; called by muse, mutect2, varscan2
- DUSP19 | c.259C>T p.L87= | Silent (SNP) | VAF 7/100 reads (7%) | catalogued as COSV100700210; called by muse, mutect2
- FEZ1 | c.1092A>T p.T364= | Silent (SNP) | VAF 12/66 reads (18%) | called by muse, mutect2, varscan2
- FLVCR2 | c.93C>A p.P31= | Silent (SNP) | VAF 73/174 reads (42%) | catalogued as COSV53163737; called by muse, mutect2, varscan2
- FSCB | c.2295G>T p.V765= | Silent (SNP) | VAF 45/210 reads (21%) | catalogued as COSV100468977; called by muse, mutect2, varscan2
- HTR1D | c.246C>A p.T82= | Silent (SNP) | VAF 20/212 reads (9%) | catalogued as COSV100024725; called by muse, mutect2
- KCNAB1 | c.930G>A p.G310= (on ENST00000490337 / NM_172160.3; = p.G299= on NM_003471.3) | Silent (SNP) | VAF 22/146 reads (15%) | catalogued as COSV100203986; called by muse, mutect2, varscan2
- KPRP | c.36G>T p.P12= | Silent (SNP) | VAF 29/101 reads (29%) | catalogued as rs761781923, COSV64222236, COSV64223096; called by muse, mutect2, varscan2
- KRT82 | c.447G>A p.E149= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV57787419; called by muse, mutect2, varscan2
- LSP1 | c.528C>A p.P176= | Silent (SNP) | VAF 27/221 reads (12%) | catalogued as COSV61137836; called by muse, mutect2, varscan2
- LUZP2 | c.915A>C p.A305= | Silent (SNP) | VAF 19/140 reads (14%) | catalogued as COSV61219524; called by muse, mutect2, varscan2
- MMP3 | c.1128C>T p.I376= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV55408311; called by muse, mutect2
- MSI2 | c.378A>C p.V126= | Silent (SNP) | VAF 25/194 reads (13%) | catalogued as COSV52369308; called by muse, mutect2, varscan2
- NCAM1 | c.840C>T p.N280= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as rs1293661395, COSV57520058; called by muse, mutect2
- OR1J2 | c.486C>A p.L162= | Silent (SNP) | VAF 14/144 reads (10%) | catalogued as COSV58945409; called by muse, mutect2, varscan2
- OR4M1 | c.453G>T p.G151= | Silent (SNP) | VAF 70/193 reads (36%) | catalogued as COSV60063785; called by muse, mutect2, varscan2
- OR7G1 | c.138C>G p.L46= | Silent (SNP) | VAF 18/118 reads (15%) | catalogued as COSV53319131, COSV99528779; called by muse, mutect2, varscan2
- PCDHA8 | c.60C>A p.L20= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV65340726; called by muse, mutect2, varscan2
- PCDHB11 | c.2157G>T p.A719= | Silent (SNP) | VAF 19/110 reads (17%) | catalogued as COSV61314045, COSV61314188; called by muse, mutect2, varscan2
- PLA2R1 | c.2544C>T p.L848= | Silent (SNP) | VAF 18/145 reads (12%) | catalogued as rs1560166743, COSV51787435; called by muse, mutect2, varscan2
- PNPLA8 | c.1944A>G p.P648= | Silent (SNP) | VAF 16/107 reads (15%) | catalogued as rs771282623, COSV57555046; called by muse, mutect2, varscan2
- PRAMEF1 | c.405A>G p.A135= | Silent (SNP) | VAF 32/212 reads (15%) | catalogued as COSV60019394; called by muse, mutect2, varscan2
- PSG7 | c.321G>T p.L107= | Silent (SNP) | VAF 44/611 reads (7%) | catalogued as COSV68446805; called by muse, mutect2
- QPCTL | c.270A>T p.P90= | Silent (SNP) | VAF 18/193 reads (9%) | catalogued as COSV99171222; called by muse, mutect2, varscan2
- RHAG | c.729G>T p.T243= | Silent (SNP) | VAF 32/141 reads (23%) | catalogued as COSV57706648; called by muse, mutect2, varscan2
- SAMSN1 | c.633G>T p.V211= | Silent (SNP) | VAF 36/190 reads (19%) | catalogued as COSV53478106; called by muse, mutect2, varscan2
- WSCD1 | c.1254T>A p.I418= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as rs1392012900, COSV58498706; called by muse, mutect2, varscan2
- ZNF678 | c.1266C>T p.S422= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV59388946; called by muse, mutect2
- ZNF79 | c.237T>G p.L79= | Silent (SNP) | VAF 27/236 reads (11%) | catalogued as COSV61071986; called by muse, mutect2
- NFASC | c.2471-1392C>T | Intron (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2
